Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A7LX, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A7LX-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Report Patient

Name

Demographics (for

verification purposes)

Date of Birth:

Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

- A. # 8 lymph node
- B. Portal lymph node
- C. Whipple's
- D. Retroperitoneal margin
- E. Gallbladder

Clinical Information

4 cm pancreatic tumor- head of pancreas

ICD O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head
C25.0

Jan 10/10/13

Diagnosis

A. Lymph node, (#8), Excision:

- Metastatic ductal adenocarcinoma (1/1). Extranodal soft tissue extension is seen.

B. Lymph Nodes (Portal), Excision:

- Two benign lymph nodes are present (0/2).

C. Head of Pancreas and Portion of Duodenum, Whipple Resection:

- Invasive moderately-differentiated ductal adenocarcinoma
- See synoptic report for details

D. Soft Tissue, (Retroperitoneal Margin), Resection:

- Invasive adenocarcinoma is present.

E. Gallbladder, Cholecystectomy

- Acute and chronic cholecystitis
- Negative for malignancy

Reported by:

Electronically signed by:

[page 2 of 3]
Verified:

Responsible Resident:

Synoptic Report

C: Pancreas (Exocrine), Macroscopic

SPECIMEN:

Head of pancreas

Duodenum

Common bile duct

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

Uncinate process

TUMOR SIZE:

Greatest dimension: 5.5 cm

Additional dimensions: 4.5 cm x 4.0 cm

C: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades ampulla of Vater or sphincter of Oddi

Tumor invades duodenal wall

Tumor invades retroperitoneal soft tissue

Tumor invades extrapancreatic common bile duct

MARGINS:

Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 6

Number involved: 4

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

None identified

CLINICAL HISTORY:

Not specified

Gross Description

Received are specimen containers A to E. All requisitions and specimen containers are labelled with the patient's name. The cassettes and are labelled with the

A. Specimen is received fresh. The container is designated " # 8 lymph node". The specimen consists of a portion of gray/tan tissue, measuring 2.4 x 1.9 x 0.5 cm. One

[page 3 of 3]
possible lymph node is identified. The specimen is bisected and submitted in toto in cassettes A1 to A2.

B. Specimen is received fresh. The container is designated " Portal lymph node". The specimen consists of two lymph nodes, measuring 2.2 x 1.0 x 0.5 cm and 0.9 x 0.5 x 0.4 cm respectively, and two portions of adipose tissue, measuring 3.0 x 1.5 x 0.4 cm and 2.0 x 1.5 x 0.4 cm respectively. The specimen is submitted in toto as follows:

- B1. one lymph node bisected
- B2. one lymph node bisected
- B3/4. adipose tissue

C. Specimen is received fresh. The container is designated " Whipple's". The specimen consists of Whipple procedure specimen composed of a portion of small intestine and a portion of pancreas. The small intestine, measures 23.0 cm in length and 7.0 cm in circumference proximally and 6.5 cm in circumference distally. The small bowel resection margins are painted black. The pancreas measures approximately 7.0 x 5.5 x 4.0 cm. The pancreatic body resection margin is painted blue, the vessel bed is painted orange, and the uncinate margin is painted green. There is a white, firm tumor, measuring 5.5 x 4.5 x 4.0 cm. The tumor grossly involved the uncinate margin and is 1.7 cm from the closest pancreatic body margin. The tumor grossly involves the common bile duct and the ampulla of Vater. The remaining small bowel mucosa is unremarkable. A portion of tumor and a portion of small bowel are submitted for tumor banking. Sections are submitted as follows:

- C1. shaved margin of the common bile duct
- C2. proximal resection margin of the small intestine
- C3. distal resection margin of the small intestine
- C4. tumor with the pancreatic body margin
- C5. tumor with the uncinate margin
- C6. tumor with the common bile duct and small intestine
- C7. tumor with the uncinate margin and adjacent small bowel
- C8. tumor with the body resection margin, vessel bed and uncinate margin
- C9. tumor with the common bile duct
- C10. tumor with the ampulla of vater

D. Specimen is received fresh. The container is designated " Retroperitoneal margin". The specimen consists of a portion of tan tissue, measuring 1.1 x 0.5 x 0.4 cm. The specimen is submitted in toto in cassette D1.

E. Specimen is received fresh. The container is designated "Gallbladder". The specimen consists of a gallbladder, measuring 8.5 x 2.9 x 1.6 cm. The serosa is smooth and unremarkable. The cystic duct is patent. The mucosa has a dark green color and is unremarkable. The lumen contains dark red/dark green fluid. No stones are identified. The wall measures 0.3 to 0.2 cm in thickness. No lymph node is identified. Representative sections are submitted in cassette E1.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 1dde14b8-4879-462f-85f8-30f011521221 (TCGA-IB-A7LX.75710768-32CF-40B2-92B4-BED9E1EF39C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).